Gene-level copy-number profile of tumor specimen TCGA-95-7562-01A from TCGA case TCGA-95-7562, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 71.2 years (26,000 days).
Specimen TCGA-95-7562-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.99d0cb98-aa5b-457c-8959-0e47dd6eb1a2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-95-7562-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/88218404-8f70-4afc-9d49-d053bf49ad0e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 2: 10,608; copy number 3: 12,181; copy number 4: 14,513; copy number 5: 9,771; copy number 6: 1,990; copy number 7: 6,498; copy number 8: 2,267; copy number 9: 685; copy number 12: 209; copy number 13: 319; copy number 14: 518; copy number 15: 216.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-95-7562-01A-11D-2237-01): tumor purity 0.55, ploidy 3.68, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,859,158–89,556,641, 41 genes: KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H, LIPA, IFIT2, AL353751.1, IFIT3, IFIT6P, IFIT1B, IFIT1, IFIT5, SLC16A12, SLC16A12-AS1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,947 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:83,200,952–84,164,564, 6 genes, copy number 13: AC090132.1, AC090132.2, LINC01419, AC015522.1, TPM3P3, AC012400.1.
- chr8:96,142,333–100,958,180, 98 genes, copy number 12 (within-gene range 8–12) (broad region; genes not listed).
- chr8:101,177,878–107,963,516, 111 genes, copy number 12 (within-gene range 8–12) (broad region; genes not listed).
- chr14:18,333,726–56,730,535, 956 genes, copy number 9–15 (within-gene range 3–15) (broad region; genes not listed).
- chr14:80,197,526–98,351,664, 284 genes, copy number 9–14 (within-gene range 3–14) (broad region; genes not listed).
- chr14:98,711,613–106,643,585, 492 genes, copy number 9–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
